CCDI case PBCJBY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/9845bd52-45ae-4366-95b0-62804bb0e9a1

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.7 years (5,352 days).

Biospecimens (3 samples)
- Sample 0DTYAJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTYAS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTYB2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
